Gene-level copy-number profile of tumor specimen ALCH-B47R-TTP1-A from ALCHEMIST case ALCH-B47R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,010 days).
Specimen ALCH-B47R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7ef6978c-a7ff-4e48-a322-790f86494702.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B47R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/c262a727-04f1-43b9-a021-042f7ce0f6b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,048; copy number 2: 54,983; copy number 3: 760; copy number 4: 69; copy number 6: 3; copy number 7: 2; copy number 8: 3; copy number 9: 2; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr22:18,178,038–18,404,206, 3 genes, copy number 6–9: FAM230D, GGTLC5P, PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene, copy number 6 (within-gene range 4–6): AC023490.2.
- chr22:18,605,355–18,611,919, 3 genes, copy number 8: AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,636,445–18,719,341, 3 genes, copy number 7–15: CA15P2, PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
